Gene-level copy-number profile of tumor specimen TCGA-BS-A0TI-01A from TCGA case TCGA-BS-A0TI, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 64.9 years (23,705 days).
Specimen TCGA-BS-A0TI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.d631ccd7-7f32-49ff-8d94-071ea56ae0e8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BS-A0TI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7226462f-131c-4d8c-8bb8-c2454766d273

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,470; copy number 2: 34,931; copy number 3: 11,657; copy number 4: 3,275; copy number 5: 1,889; copy number 6: 73; copy number 7: 278; copy number 8: 241.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BS-A0TI-01A-11D-A102-01): tumor purity 0.53, ploidy 4.26, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,481 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:6,495,651–60,554,467, 863 genes, copy number 5–6 (broad region; genes not listed).
- chr2:73,640,723–74,893,359, 69 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:70,972–30,130,483, 522 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:103,175,133–106,908,980, 55 genes, copy number 5: DPY19L2P2, S100A11P1, PMPCB, DNAJC2, PSMC2, RPS29P16, SLC26A5, Y_RNA, Y_RNA, AC005064.1, RELN, RN7SKP86, ORC5, LHFPL3, EIF4BP6, LHFPL3-AS1, AC091286.1, LHFPL3-AS2, RN7SL8P, AC007384.1, LINC01004, KMT2E-AS1, KMT2E, AC005070.3, SRPK2, AC005070.1, AC005070.2, AC004884.1, RWDD4P1, AC004884.2, RNU6-1322P, PUS7, AC073073.1, RINT1, EFCAB10, AC073073.2, YBX1P2, ATXN7L1, AC005099.1, CDHR3, AC004836.1, SYPL1, DCAF13P1, RNU6-392P, NAMPT, AC007032.1, LARP1BP2, AC004917.1, AC005050.3, AC005050.1, AC005050.2, CCDC71L, LINC02577, RNA5SP236, PIK3CG.
- chr7:128,207,872–149,773,588, 553 genes, copy number 5–8 (broad region; genes not listed).
- chr7:157,466,231–158,704,804, 18 genes, copy number 5: AC006372.3, AC006372.1, AC006372.2, AC006372.4, PTPRN2, MIR153-2, AC005481.1, AC006003.1, PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2.
- chr10:95,237,572–95,561,414, 2 genes, copy number 7 (within-gene range 4–7): PDLIM1, SORBS1.
- chr11:119,608,423–135,075,908, 324 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:66,767–2,004,535, 43 genes, copy number 6: IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940, DCP1B.
- chr12:2,004,666–2,049,463, 3 genes, copy number 6: AC005342.1, CACNA1C-IT1, CACNA1C-IT2.
- chr18:55,893,038–57,803,315, 29 genes, copy number 5 (within-gene range 2–5): AC009271.1, AC006305.1, AC009271.2, LINC01905, AC006305.2, SNORA73, LINC01539, AC006305.3, TXNL1, WDR7, Y_RNA, AC012301.1, U3, WDR7-OT1, AC012301.2, LINC-ROR, AC100775.1, BOD1L2, LINC02565, RNU6-737P, ST8SIA3, AC090340.1, ONECUT2, FECH, AC100847.1, NARS1, AC027097.1, AC027097.2, ATP8B1.

Autosomal genes at a single copy (total copy number 1): 7,160. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
